CCDI case PBBSXR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d2a6aa22-8c90-4816-bf89-ce45d3972b7b

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.4 years (5,975 days).

Biospecimens (3 samples)
- Sample 0DG9FQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DG9FV, 0DGBC7 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
